Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7687, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7687-01A (Primary Tumor).

Pathology Report for Subject [REDACTED]

Discussion: Numerous MIB-1 cells are scattered throughout in the confluent cellular areas, labeling index of 9.5% is calculated. This level of proliferative activity is virtually always seen in high grade tumors. It is unclear why more mitoses were not identified in the specimen, but with this MIB-1 labeling index and the degree of cellularity and atypia, a classification of anaplastic/grade III is warranted.

Microscopic Description: Sections demonstrate a neoplasm that is diffusely distributed in the gray and white matter. This is composed of cells with round nuclei, cytoplasm and prominent perinuclear halos. Perineural satellitosis is prominent. Despite areas of confluent cellularity and moderate Atypia, only a single mitotic figure is seen in over fifty high power fields. Neither microvascular proliferation nor necrosis is present.

Diagnosis: Anaplastic Oligodendroglioma (WHO grade III).

Source: NCI Genomic Data Commons file ecf8e14b-4b69-4cae-a1f1-7506a79253be (TCGA-HT-7687.F1BFF6BC-CBA4-4986-B4A1-E04DAE6F259E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).